Somatic mutation profile of tumor specimen TCGA-2G-AALS-01A (aliquot TCGA-2G-AALS-01A-12D-A42Y-10) from TCGA case TCGA-2G-AALS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9b63dd5-b702-4224-b101-46caf7e2ee81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALS-10A (Blood Derived Normal), aliquot TCGA-2G-AALS-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b56a04-9f81-4e57-b17b-d32f5940f9c7

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA9 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1486018746; called by muse, mutect2, varscan2
- MESP2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MYH7 | c.2840G>A p.C947Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PIK3C2G | c.2384T>C p.L795P (on ENST00000676171; = p.L754P on NM_004570.5) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SP1 | c.1006A>C p.M336L (on ENST00000327443 / NM_138473.3; = p.M329L on NM_003109.1) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAU2 | c.1502A>C p.E501A (on ENST00000524300 / NM_001164380.2; = p.E469A on NM_014393.2) | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCTN1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS72 | c.562+2T>A p.X188_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- KLC2 | c.1647C>A p.L549= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, varscan2
- LRRC37B | c.2268A>G p.P756= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- FASLG | c.-20G>T | 5'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NPS | c.-30C>G | 5'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
